Surgical pathology report (de-identified scan), TCGA case TCGA-P8-A6RX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of Pittsburgh, specimen TCGA-P8-A6RX-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

RETROCAVAL MASS, OPEN RESECTION OF RETROPERITONEAL MASS (36 GRAMS) -
PARAGANGLIOMA, 6.5 CM.

6/20/13

6/20/13

Source: NCI Genomic Data Commons file dab73d3a-73a1-43a1-b2f1-a5bf6c8f43fe (TCGA-P8-A6RX.6225EA0C-D8BE-472D-BF48-CBD8876D3A48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).